Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6385, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6385-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:
A. PROSTATE

TCGA - G9 - 6385

SPECIMEN(S):
A. PROSTATE

GROSS DESCRIPTION:

A. PROSTATE

Received fresh is a 41g resected prostate measuring 6.2cm from right to left, 4.2cm from anterior to posterior, and 3.5cm from apex to base, with attached right and left seminal vesicles and vas deferens. The specimen is inked as follows: Anterior-Orange, Posterior-Black, Apex-Red, Base-Blue, Right-Green, and Left-Yellow. After removal of the apex and base, the remaining prostate weight is 29g. The specimen is serially sectioned from apex to base to reveal firm tan fibrous parenchyma. A 1.4cm firm yellow irregular lesion is identified 0.4cm from the anterior margin. The attached right and left seminal vesicles are 2.8 x 1 x 0.6cm and 2.1 x 0.6 x 0.3cm, respectively, are sectioned to beige tan cystic tissue with no gross evidence of tumor involvement. The attached right and left segments of vas deferens are 2.7 x 0.4cm and 2.6 x 0.8cm, respectively, are sectioned to reveal firm tan tubular structure with no gross evidence of tumor involvement. A portion of the specimen is submitted for tissue procurement (Levels II-III). The remainder of the specimen is submitted as follows:

A1-A2: right apex
A3-A4: left apex
A5: level I right anterior
A6: level I right posterior
A7: level I left anterior
A8: level I left posterior
A9: level II right anterior capsule
A10: level II right posterior capsule
A11: level II left anterior capsule
A12: level II left posterior capsule
A13: level III right anterior with lesion
A14: level III right posterior
A15: level III left anterior with lesion
A16: level III left posterior
A17: level IV right anterior capsule
A18: level IV right posterior capsule
A19: level IV left anterior capsule
A20: level IV left posterior capsule
A21-A22: right base with periurethral margin
A23-A24: left base with periurethral margin
A25: right lateral base
A26: left lateral base
A27: right seminal vesicle and vas deferens
A28: left seminal vesicle and vas deferens

DIAGNOSIS:

A. PROSTATE, PROSTATECTOMY:
- PROSTATIC ADENOCARCINOMA, GLEASON GRADE 3 + 4 (7/10).
- SEE SYNOPSIS REPORT.

SYNOPSIS REPORT - PROSTATE GLAND

Specimens Involved
Specimens: A: PROSTATE

Location: Left

Right

Posterior lateral

Basal

Anterior

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma 8140/3

[page 2 of 2]
[REDACTED]

Multicentricity: Yes
Gland Involvement: 5%
Gleason Grade/Sum:: Grade 3 + 4 , Sum 7
High Grade PIN Present: Yes
Perineural Invasion: No
Vascular/Lymphatic Invasion: No
Seminal Vesicle Invasion: No
Periprostatic Fat Involved: No
Bladder Neck Involved: No
Margins Involvement: No
Frozen Performed: No
Lymph Nodes: No lymph nodes sampled
Other Pathologic Findings: BPH
Pathological Staging (pTNM): pT2cNXMX T 2c N X M X
Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition
pT2c: Tumor involves both lobes

CLINICAL HISTORY:

None provided.

PRE-OPERATIVE DIAGNOSIS:

Prostate carcinoma.

[REDACTED]

Source: NCI Genomic Data Commons file 5546dfd3-43ba-40ae-a38a-f19abdf3e955 (TCGA-G9-6385.3027C5CD-F972-469C-A9F2-9A72B83A86C8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).